TARGET case TARGET-30-PARYNK — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/117e4e39-d43d-5d08-be3e-9bd8c1e5d5e5

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C77.2; Tissue or organ of origin: Intra-abdominal lymph nodes; Classification of tumor: primary; Age at diagnosis: 6.2 years (2,279 days); Year of diagnosis: 2008; Days to last follow up: 3,794 days (10.4 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 3,794 days (10.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,794; Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARYNK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARYNK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3794
- Protocol: ANBL00B1, ANBL0532
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- ICDO Description: Intra-abdominal lymph nodes Abdominal lymph node Aortic lymph node Celiac lymph node Colic lymph node Common duct lymph node Gastric lymph node Hepatic lymph node Ileocolic lymph node Inferior mesenteric lymph node Intestinal lymph node Lumbar lymph node
- Percent Necrosis: 10-15
- Percent Tumor v/s Stroma: 90/10
